Somatic mutation profile of tumor specimen TCGA-W5-AA2M-01A (aliquot TCGA-W5-AA2M-01A-11D-A46P-09) from TCGA case TCGA-W5-AA2M, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.3 years (17,989 days).
Specimen TCGA-W5-AA2M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69aa7c3e-6396-424f-a78a-56f87f26d927.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2M-10A (Blood Derived Normal), aliquot TCGA-W5-AA2M-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd88dd5-4f9b-4096-a1e0-e3d1aa06ead6

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 25, Silent 13, Nonsense Mutation 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as rs376576925, CM981381, COSV62193951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR7A3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs373169386; called by muse, mutect2, varscan2
- ATP13A2 | c.2498T>C p.I833T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs1196597956; called by muse, mutect2, varscan2
- CCDC141 | c.2708G>A p.R903K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs1250207924; called by muse, varscan2
- CXCR4 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs147198552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX36 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as rs753647774, COSV100274082; called by muse, mutect2, varscan2
- KCTD13 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs759086438; called by muse, mutect2, varscan2
- LARP6 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1307852079; called by muse, mutect2, varscan2
- MAP3K5 | c.2611A>G p.I871V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs961557395; called by muse, mutect2, varscan2
- NOS1 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57621683; called by muse, mutect2, varscan2
- RAD50 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs587782282; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC7A11 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs771913516, COSV54928571; called by muse, mutect2, varscan2
- SNRPG | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as rs1471721376; called by muse, mutect2
- TESK2 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as rs199634022; called by muse, mutect2, varscan2
- ZNF701 | c.571C>T p.R191* (on ENST00000301093; = p.R125* on NM_018260.3) | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs780610486, COSV99990920; called by muse, mutect2, varscan2
- CS | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- DCANP1 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.881); called by muse, mutect2
- DNAJC5B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM71A | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- FOLR1 | c.287G>C p.C96S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IL17RE | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO5 | c.1274A>G p.Q425R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- LPA | c.5471G>T p.C1824F | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMEL1 | c.1895T>G p.M632R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OFCC1 | n.127G>T | Splice Region (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- PGGHG | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2
- PIP4P1 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RUNDC3B | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SERPINA12 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- ARHGAP22 | c.285C>T p.P95= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs147995942; called by muse, mutect2, varscan2
- CABIN1 | c.4554G>T p.L1518= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CFAP70 | c.42C>T p.T14= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs766568806, COSV100160179; called by muse, mutect2, varscan2
- MS4A12 | c.705C>T p.V235= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- NEXMIF | c.1410C>A p.G470= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs762687643; called by muse, varscan2
- NRXN3 | c.1830C>T p.N610= (on ENST00000557594 / NM_001272020.2; = p.N1034= on NM_004796.6) | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs138628835; called by muse, mutect2, varscan2
- OR2AK2 | c.714T>A p.V238= | Silent (SNP) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- PFAS | c.1989G>A p.Q663= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100119100; called by muse, mutect2
- POU1F1 | c.510C>A p.I170= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- PPFIA1 | c.966C>T p.I322= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV99558221; called by muse, mutect2
- TBCA | c.126T>C p.A42= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs201720489; called by muse, mutect2, varscan2
- TMEM31 | c.33A>G p.Q11= | Silent (SNP) | VAF 15/19 reads (79%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.882C>T p.I294= (on ENST00000452346; = p.I168= on NM_001042575.2) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs749033644, COSV69979535; called by muse, mutect2, varscan2
